Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A17T, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A17T-01A (Primary Tumor).

[page 1 of 4]
1CD-0-3

Adenocarcinoma, Endometrioid, NOS

8380/3 12/4/10

Site Code: Endometrium (54.1) *fw*

Surgical Pathology

DIAGNOSIS:

A. Uterus, hysterectomy: Endometrial adenocarcinoma, endometrioid type, FIGO grade 2 (of 3) is identified forming a polypoid mass (3.4

x 3.1 x 0.9 cm) circumferentially involving the endometrial cavity.

The tumor invades 0.5 cm into the myometrium (total myometrial

thickness, 2.0 cm). The tumor does not involve the endocervix.

Lymphovascular space invasion is not identified. The margins are

negative for tumor. Multiple (2) subserosal leiomyomata (0.5 cm and

2.3 cm in greatest dimension) are identified in the myometrium.

[AJCCpt1bNOMX].

B. Ovary and fallopian tube, portion left, partial salpingo-oophorectomy: The left fallopian tube and ovary are without diagnostic abnormality.

C. Ovary and fallopian tube, right, salpingo-oophorectomy: The right fallopian tube and ovary are without diagnostic abnormality.

D. Ovary and fallopian tube, remainder left, completion salpingo-oophorectomy: Ovarian tissue and fallopian tube are without diagnostic abnormality.

E. Lymph nodes, left pelvic, lymphadenectomy: Multiple (14) left pelvic lymph nodes are negative for tumor.

F. Lymph nodes, right pelvic, lymphadenectomy: Multiple (10) right pelvic lymph nodes are negative for tumor.

This final pathology report is based on the gross/macroscopic

[page 2 of 4]
examination and the frozen section histologic evaluation of the specimen(s). Hematoxylin and Eosin (H&E) permanent sections are reviewed to confirm these findings. Any substantive changes identified on permanent section review will be reflected in a revised report.

GROSS DESCRIPTION:

A. Received fresh labeled "uterus" is an 85.0 gram uterus and cystic cervix. The uterine serosa smooth. There is a 3.4 x 3.1 x 0.9 cm polypoid mass involving the entire endometrial cavity. The mass grossly appears to invade 0.4 cm into the 2.0 cm thick myometrium. There are multiple (2) subserosal leiomyomata (0.5 cm and 2.3 cm/calcified in greatest dimension) in the myometrium. Representative sections are submitted.

B. Received fresh labeled "left tube and ovary" is a 1.2 x 1.0 x 0.7 cm portion of ovary with a 3.7 x 0.4 cm attached fallopian tube. The ovary has a smooth outer surface and solid cut surface. Representative sections are submitted.

C. Received fresh labeled "right tube and ovary" is a 2.2 x 1.4 x 1.2 cm ovary with a 5.2 x 0.5 cm attached fallopian tube. The ovary has a ragged outer surface with hemorrhagic adhesions and a solid cut surface. Representative sections submitted.

D. Received fresh labeled "additional left ovary and fallopian tube" is a 3.6 x 1.3 x 1.0 cm remainder of ovary with a 6.3 x 0.5 cm attached remainder of fallopian tube. The ovary has a smooth outer

[page 3 of 4]
surface and a solid cut surface. Representative sections submitted.

E. Received fresh labeled "left pelvic nodes laparoscopic" is a 5.4 x 3.3 x 1.7 cm aggregate of adipose and lymphatic tissue. Multiple (13) lymph nodes are identified. All lymphatic tissue submitted.

F. Received fresh labeled "right pelvic nodes laparoscopic" is a 5.2 x 3.2 x 1.5 cm aggregate of adipose and lymphatic tissue. Multiple (10) lymph nodes are identified. All lymphatic tissue submitted.

BLOCK SUMMARY:

Part A: Uterus

- 1 Endometrium-1
- 2 Endometrium-2
- 3 Endometrium-3
- 4 Endometrium-4
- 5 Endometrium-5
- 6 Endometrium-6
- 7 Lower uterine segment
- 8 Cervix

Part B: Left Ovary and fallopian tube

- 1 Left fallopian tube
- 2 Left ovary

Part C: Right Ovary and fallopian tube

- 1 Right fallopian tube
- 2 Right ovary

Part D: Additional Left Ovary & fallopian tube

- 1 Addition Lt tube
- 2 Addition Lt ovary

Part E: Left Pelvic Lymph Nodes

- 1 Lt pelvic LN 4 (E1)
- 2 Lt pelvic LN 1of2 (E2)
- 3 Lt pelvic LN 2of2 (E2)
- 4 Lt pelvic LN 1of3 (E3)
- 5 Lt pelvic LN 2of3 (E3)

[page 4 of 4]
- 6 Lt pelvic LN 3of3 (E3)
- 7 Lt pelvic LNs-2(E4)
- 8 Lt pelvic LNs-2(E5)
- 9 Lt pelvic LNs-4(E6)

Part F: Right Pelvic Lymph Nodes

- 1 Rt pelvic LN 3 (F1)
- 2 Rt pelvic LN 1of3 (F2)
- 3 Rt pelvic LN 2of3 (F2)
- 4 Rt pelvic LN 3of3 (F2)
- 5 Rt pelvic LN 2 (F3)
- 6 Rt pelvic LN 2 (F4)
- 7 Rt pelvic LN 2 (F5)

Source: NCI Genomic Data Commons file 9364d98d-e649-4ad5-9e53-635ab99fae0e (TCGA-D1-A17T.D5927418-5A2B-477D-9917-7CE912628CA4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).